Somatic mutation profile of tumor specimen ALCH-ADYW-TTP1-A (aliquot ALCH-ADYW-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADYW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,912 days).
Specimen ALCH-ADYW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdc433ef-1361-412e-893a-4c5852fdf18e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADYW-NB1-A (Blood Derived Normal), aliquot ALCH-ADYW-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff89ca8e-c993-430a-a0c8-7236c7349ca3

The open-access MAF lists 252 somatic variants for this specimen: 171 protein-altering or splice-affecting, 51 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 51, Intron 13, Nonsense Mutation 12, 3'UTR 6, Splice Site 6, RNA 4, 5'Flank 4, Frame Shift Del 3, 5'UTR 3, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 80/823 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52588411, COSV52590494; called by muse, mutect2
- ACE2 | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV53023553; called by muse, mutect2, varscan2
- ADAMTS20 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV67140364; called by muse, mutect2
- ADAMTS3 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99709885; called by muse, mutect2, varscan2
- AMIGO2 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56974922; called by muse, mutect2
- ANKRD17 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 51/369 reads (14%) | catalogued as COSV100429501; called by muse, mutect2, varscan2
- ASAP2 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 149/528 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55631400; called by muse, mutect2, varscan2
- ATM | c.9112C>T p.Q3038* | Nonsense Mutation (SNP) | VAF 96/343 reads (28%) | catalogued as COSV53739959; called by muse, mutect2, varscan2
- ATP2B3 | c.1223C>A p.P408Q | Missense Mutation (SNP) | VAF 91/509 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV54849198; called by muse, mutect2, varscan2
- CACNA1C | c.4567C>G p.R1523G | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59763977; called by muse, mutect2, varscan2
- CASP8AP2 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52748067; called by muse, mutect2, varscan2
- CHD2 | c.4738C>T p.R1580C | Missense Mutation (SNP) | VAF 42/435 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67713006; called by muse, mutect2
- CHST2 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as rs776713198; called by muse, mutect2, varscan2
- CLEC4F | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as rs1553396030; called by muse, mutect2
- COL2A1 | c.1267-1G>T p.X423_splice | Splice Site (SNP) | VAF 64/664 reads (10%) | catalogued as COSV100477279, COSV61529656; called by muse, mutect2
- COL3A1 | c.4036C>A p.P1346T | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.783); catalogued as COSV58596158; called by muse, mutect2, varscan2
- CSMD1 | c.3047A>T p.N1016I (on ENST00000520002; = p.N1015I on NM_033225.6) | Missense Mutation (SNP) | VAF 70/873 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59336754; called by muse, mutect2
- CSMD2 | c.2197G>T p.V733F | Missense Mutation (SNP) | VAF 38/469 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV53907596, COSV53925434; called by muse, mutect2
- CSMD3 | c.10249C>A p.P3417T (on ENST00000297405 / NM_001363185.1; = p.P3248T on NM_052900.3) | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs919848950, COSV99843997; called by muse, mutect2
- CTNND2 | c.2692G>T p.V898L | Missense Mutation (SNP) | VAF 63/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58864026; called by muse, mutect2, varscan2
- DCAF8L2 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 122/710 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70550601, COSV70552556; called by muse, mutect2, varscan2
- DCST1 | c.1754A>C p.K585T | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294608583; called by muse, mutect2, varscan2
- DST | c.4250A>G p.Y1417C (on ENST00000361203 / NM_001374722.1; = p.Y1091C on NM_001723.6) | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs201467113; called by muse, mutect2, varscan2
- ERICH6B | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as rs1409035432; called by muse, mutect2, varscan2
- GABRB3 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 52/664 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1314610, COSV54656624, COSV54667501; called by muse, mutect2
- GPC6 | c.1586C>G p.S529C | Missense Mutation (SNP) | VAF 401/1196 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV65507125; called by muse, mutect2, varscan2
- IGKV1D-12 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs530711240; called by muse, mutect2, varscan2
- KCNA4 | c.1513A>T p.T505S | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100069306; called by muse, mutect2
- LRP1B | c.6427G>T p.G2143W | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253520, COSV101260818; called by muse, mutect2, varscan2
- MAP3K19 | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV59639008; called by muse, mutect2, varscan2
- MAPK4 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1469729608; called by muse, mutect2, varscan2
- MARCHF10 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV60886641, COSV60890901; called by muse, mutect2, varscan2
- MINAR2 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 44/621 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV57993612; called by muse, mutect2
- MTF2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV64770340; called by muse, mutect2
- NPAS3 | c.1168C>T p.Q390* (on ENST00000356141 / NM_001164749.2; = p.Q358* on NM_022123.3) | Nonsense Mutation (SNP) | VAF 90/217 reads (41%) | catalogued as COSV60821846; called by muse, mutect2, varscan2
- OR2G3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60680996; called by muse, mutect2, varscan2
- P3H4 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1428198564; called by muse, mutect2, varscan2
- PBX4 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs201537948; called by muse, mutect2
- PCDHB8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 52/1086 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV50753684; called by muse, mutect2
- PDHA2 | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 45/622 reads (7%) | catalogued as rs745717933; called by muse, mutect2
- PKM | c.379A>T p.S127C | Missense Mutation (SNP) | VAF 157/965 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs766141000; called by muse, mutect2, varscan2
- PLPPR4 | c.1967G>T p.S656I | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV100926855, COSV64565010; called by muse, mutect2, varscan2
- PLPPR4 | c.2170C>G p.R724G | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV64564167, COSV64567688; called by muse, mutect2
- PLXND1 | c.1217C>G p.A406G | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1157538964; called by muse, mutect2
- RAI2 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 174/658 reads (26%) | catalogued as COSV100518398; called by muse, mutect2, varscan2
- RBM10 | c.2080T>A p.Y694N | Missense Mutation (SNP) | VAF 121/856 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV104412033; called by muse, mutect2, varscan2
- ROBO2 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 52/736 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59936835; called by muse, mutect2
- SAXO2 | c.254-1G>C p.X85_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as COSV59753996; called by muse, mutect2
- SEC24A | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); catalogued as rs1167841615; called by muse, mutect2
- SHISA6 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 62/930 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1422242613, COSV58648990; called by muse, mutect2
- SIRPG | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 64/786 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs995344303, COSV53809933; called by muse, mutect2
- SLC18A1 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1411062954; called by muse, mutect2, varscan2
- SP3 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV59471818; called by muse, mutect2, varscan2
- SPON2 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 80/632 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as rs1468537718; called by muse, mutect2, varscan2
- SPTA1 | c.6508C>A p.L2170I | Missense Mutation (SNP) | VAF 80/1086 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.315); catalogued as COSV63752256; called by muse, mutect2
- SUN5 | c.1010C>A p.A337E | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); catalogued as COSV62182336; called by muse, mutect2, varscan2
- SYCP1 | c.2846G>A p.R949K | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs748418206; called by muse, mutect2, varscan2
- THBD | c.1390T>A p.C464S | Missense Mutation (SNP) | VAF 66/622 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65703197; called by muse, mutect2, varscan2
- TYR | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as CM041479; called by muse, mutect2
- ZNF729 | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs759794428; called by muse, mutect2, varscan2
- ZNF813 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as COSV101125028; called by muse, mutect2, varscan2
- ZNF98 | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63337207; called by muse, mutect2, varscan2
- ADAMTS13 | c.3044+2T>A p.X1015_splice | Splice Site (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMER3 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- AOC1 | c.261T>G p.D87E | Missense Mutation (SNP) | VAF 48/680 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ARX | c.1245C>A p.D415E | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ASCC3 | c.3618C>G p.F1206L | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATP4A | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 33/416 reads (8%) | called by muse, mutect2
- BCL7B | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.161); called by muse, mutect2
- C3orf84 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C8orf34 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- CACNA1C | c.2479C>A p.Q827K | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CAMTA1 | c.4966G>T p.V1656L | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2
- CARMIL2 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CCSER1 | c.1642G>C p.A548P | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.79); called by muse, mutect2
- CEACAM1 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CETP | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 74/845 reads (9%) | called by muse, mutect2
- CFAP47 | c.1502T>A p.L501* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- CFAP58 | c.1260A>T p.E420D | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CLCN1 | c.2595+2T>G p.X865_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- CLIC5 | c.1009G>T p.G337W (on ENST00000185206 / NM_001370649.1; = p.G178W on NM_016929.5) | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN5 | c.1978T>A p.S660T | Missense Mutation (SNP) | VAF 183/504 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CPD | c.2462A>T p.H821L | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CPOX | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, varscan2
- CRNKL1 | c.1048A>T p.I350F | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- DBF4 | c.1432A>T p.R478W | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- DCAF12L2 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- DMD | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 139/1050 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DTX3L | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFHC2 | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FAM25A | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 126/783 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FAT3 | c.12612C>G p.S4204R | Missense Mutation (SNP) | VAF 53/568 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2
- FER1L6 | c.4849A>T p.T1617S | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FSIP2 | c.12077T>C p.L4026P | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- GABBR2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GDF10 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- GPR6 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 95/449 reads (21%) | called by muse, mutect2, varscan2
- HAP1 | c.73T>G p.C25G | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HAS1 | c.1586G>A p.W529* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- HIVEP3 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2
- IGF1R | c.452A>C p.Y151S | Missense Mutation (SNP) | VAF 77/884 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITGA3 | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LARP4B | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 94/556 reads (17%) | called by muse, mutect2, varscan2
- LRBA | c.7150G>T p.D2384Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LUC7L | c.246dup p.E83* | Frame Shift Ins (INS) | VAF 41/221 reads (19%) | called by mutect2, pindel, varscan2
- MAP3K3 | c.1408A>T p.T470S | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MAP3K4 | c.4451G>T p.C1484F | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MDGA2 | c.2551C>G p.P851A (on ENST00000399232 / NM_001113498.2; = p.P553A on NM_182830.4) | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- MED12L | c.4239G>T p.L1413F | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MGAM | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- MGAT5 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 107/650 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NRG1 | c.806A>C p.K269T (on ENST00000405005 / NM_013964.5; = p.K274T on NM_013956.5) | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR2C1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- OR5P2 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- PCDHGC4 | c.2155del p.A719Qfs*36 | Frame Shift Del (DEL) | VAF 47/498 reads (9%) | called by mutect2, pindel
- PCMTD1 | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2
- PCNT | c.8878G>A p.A2960T | Missense Mutation (SNP) | VAF 70/838 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2
- PIK3R4 | c.1829G>T p.W610L | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PITPNM1 | c.2820G>T p.M940I | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PLEKHA5 | c.1466A>C p.E489A | Missense Mutation (SNP) | VAF 52/626 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- PLXNC1 | c.3819C>A p.D1273E | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PNLIP | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); called by muse, mutect2
- PRAMEF18 | c.495C>A p.S165R | Missense Mutation (SNP) | VAF 66/1520 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- PRKG1 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.181); called by muse, mutect2
- PRPF8 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 65/511 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD23B | c.498-2A>T p.X166_splice | Splice Site (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- RBM10 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 119/652 reads (18%) | called by muse, mutect2, varscan2
- RBM45 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 27/404 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGS9 | c.87C>A p.N29K | Missense Mutation (SNP) | VAF 100/1304 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- RIBC1 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RNASEH2A | c.112A>T p.R38W | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBF2 | c.3328G>T p.V1110L | Missense Mutation (SNP) | VAF 66/770 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.145); called by muse, mutect2
- SEC16A | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 123/540 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SERINC2 | c.448A>G p.I150V (on ENST00000373709 / NM_178865.5; = p.I154V on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SIGLEC8 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SIRPB2 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 58/659 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- SLC17A5 | c.1386_1402delinsAGCAGCA p.A465Ffs*34 | Frame Shift Del (DEL) | VAF 33/317 reads (10%) | called by muse*, pindel
- SLC25A24 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2
- SLC2A9 | c.1568C>A p.P523Q | Missense Mutation (SNP) | VAF 62/583 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC36A1 | c.781T>A p.F261I | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC9C2 | c.1297+1G>T p.X433_splice | Splice Site (SNP) | VAF 14/96 reads (15%) | called by muse, varscan2
- SLITRK2 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SMIM19 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SMPD4 | c.1566G>C p.Q522H (on ENST00000409031 / NM_017951.4; = p.Q493H on NM_017751.4) | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SMYD2 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- STK11 | c.139_178del p.G47Tfs*4 | Frame Shift Del (DEL) | VAF 62/685 reads (9%) | called by mutect2, pindel
- SUV39H1 | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 100/478 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TACC2 | c.5119G>T p.G1707C | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TARM1 | c.571C>A p.L191M (on ENST00000616041 / NM_001330650.1; = p.L183M on NM_001135686.3) | Missense Mutation (SNP) | VAF 71/772 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMC3 | c.1272G>A p.E424= | Splice Region (SNP) | VAF 43/327 reads (13%) | called by muse, mutect2, varscan2
- TRAV7 | c.199C>A p.H67N | Missense Mutation (SNP) | VAF 32/539 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2
- TRBV2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRO | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRPM7 | c.5315G>T p.G1772V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.97771G>T p.V32591F (on ENST00000591111; = p.V25167F on NM_003319.4) | Missense Mutation (SNP) | VAF 34/445 reads (8%) | PolyPhen benign (0.033); called by muse, mutect2
- TTN | c.34816G>T p.A11606S (on ENST00000591111; = p.A10679S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TYR | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 173/893 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- UCN3 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 168/1033 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A1 | c.1148G>T p.C383F | Missense Mutation (SNP) | VAF 48/700 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UQCC1 | c.880T>G p.Y294D | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- WDR97 | c.2150C>T p.T717I | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZAN | c.1541A>T p.Q514L | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2
- ZFHX4 | c.4757G>T p.S1586I | Missense Mutation (SNP) | VAF 41/494 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2
- ZFHX4 | c.10079C>G p.S3360C | Missense Mutation (SNP) | VAF 117/470 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, varscan2
- ZIM2 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.368); called by muse, mutect2
- ZNF134 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZNF235 | c.773C>G p.T258R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF268 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF479 | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 32/828 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ZNF729 | c.3295A>G p.T1099A | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2
- ADGRG4 | c.987G>A p.Q329= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV99796996; called by muse, mutect2, varscan2
- ARAP2 | c.4398G>T p.G1466= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- CASQ1 | c.1071A>G p.V357= | Silent (SNP) | VAF 71/388 reads (18%) | called by muse, mutect2, varscan2
- CDH20 | c.903G>A p.L301= | Silent (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- CHI3L1 | c.966C>T p.G322= | Silent (SNP) | VAF 111/559 reads (20%) | called by muse, mutect2, varscan2
- COL3A1 | c.804C>T p.F268= | Silent (SNP) | VAF 22/335 reads (7%) | catalogued as rs267599121, COSV58585156; called by muse, mutect2
- DISP3 | c.3588C>A p.A1196= | Silent (SNP) | VAF 21/286 reads (7%) | called by muse, mutect2
- DNMBP | c.3687G>C p.L1229= | Silent (SNP) | VAF 52/342 reads (15%) | called by muse, mutect2, varscan2
- DZIP1 | c.2199T>C p.D733= (on ENST00000347108; = p.D714= on NM_014934.5) | Silent (SNP) | VAF 61/277 reads (22%) | called by muse, mutect2, varscan2
- FAT1 | c.9834C>T p.F3278= | Silent (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- FCGBP | c.8091G>T p.G2697= | Silent (SNP) | VAF 64/2526 reads (3%) | catalogued as COSV55458174; called by muse, mutect2
- FLG | c.6123T>C p.G2041= | Silent (SNP) | VAF 124/1722 reads (7%) | called by muse, mutect2
- FMO1 | c.972C>T p.I324= | Silent (SNP) | VAF 36/303 reads (12%) | catalogued as COSV61446703; called by muse, mutect2, varscan2
- HEPH | c.1464T>C p.F488= (on ENST00000343002; = p.F221= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- HIVEP3 | c.6384A>C p.P2128= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- IGSF9 | c.1740C>T p.Y580= (on ENST00000368094 / NM_001135050.2; = p.Y564= on NM_020789.4) | Silent (SNP) | VAF 64/427 reads (15%) | catalogued as rs972478844; called by muse, mutect2, varscan2
- ITIH6 | c.1458T>G p.V486= | Silent (SNP) | VAF 35/189 reads (19%) | called by muse, mutect2, varscan2
- JMJD1C | c.4188G>T p.T1396= | Silent (SNP) | VAF 44/237 reads (19%) | called by muse, mutect2, varscan2
- KCNIP1 | c.450C>T p.D150= (on ENST00000411494 / NM_001034837.3; = p.D139= on NM_014592.4) | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as rs750371234; called by muse, mutect2
- KCTD3 | c.309T>C p.T103= | Silent (SNP) | VAF 28/142 reads (20%) | called by muse, varscan2
- KIDINS220 | c.855T>G p.V285= | Silent (SNP) | VAF 29/289 reads (10%) | called by muse, mutect2, varscan2
- LRFN5 | c.2103T>C p.A701= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as COSV99984493; called by muse, mutect2, varscan2
- MED1 | c.120G>T p.V40= | Silent (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- MOSPD1 | c.66G>T p.T22= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- MTRNR2L10 | c.57C>T p.S19= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as rs1261617596; called by muse, mutect2, varscan2
- MUC16 | c.732G>A p.G244= | Silent (SNP) | VAF 23/211 reads (11%) | catalogued as rs1313070063, COSV67446004; called by muse, mutect2, varscan2
- MYCT1 | c.513G>T p.L171= | Silent (SNP) | VAF 117/643 reads (18%) | called by muse, mutect2, varscan2
- NLRP14 | c.1107C>T p.P369= | Silent (SNP) | VAF 83/583 reads (14%) | called by muse, mutect2, varscan2
- NOBOX | c.609C>A p.P203= | Silent (SNP) | VAF 96/668 reads (14%) | called by muse, varscan2
- NSUN6 | c.1101G>T p.V367= | Silent (SNP) | VAF 47/389 reads (12%) | catalogued as rs373744608; called by muse, mutect2, varscan2
- OR10X1 | c.516T>A p.S172= | Silent (SNP) | VAF 25/317 reads (8%) | called by muse, mutect2
- PBX3 | c.144C>T p.D48= | Silent (SNP) | VAF 33/358 reads (9%) | called by muse, mutect2
- PJA2 | c.1005G>A p.R335= | Silent (SNP) | VAF 24/294 reads (8%) | called by muse, mutect2
- PLAU | c.528C>A p.R176= | Silent (SNP) | VAF 43/279 reads (15%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.204G>T p.L68= | Silent (SNP) | VAF 94/905 reads (10%) | called by muse, mutect2, varscan2
- PTGS2 | c.12C>A p.R4= | Silent (SNP) | VAF 35/230 reads (15%) | catalogued as COSV66572328; called by muse, mutect2, varscan2
- PTPRCAP | c.483C>T p.L161= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs1349194790; called by muse, mutect2, varscan2
- RAB6C | c.429G>A p.R143= | Silent (SNP) | VAF 95/660 reads (14%) | catalogued as COSV101308520, COSV69339914; called by muse, mutect2, varscan2
- RAF1 | c.1857C>T p.S619= | Silent (SNP) | VAF 78/814 reads (10%) | catalogued as rs754017289, COSV50109262; ClinVar: likely benign; called by muse, mutect2
- RASAL1 | c.957T>A p.A319= | Silent (SNP) | VAF 75/384 reads (20%) | called by muse, mutect2, varscan2
- RYR2 | c.5350C>T p.L1784= | Silent (SNP) | VAF 65/1005 reads (6%) | called by muse, mutect2
- RYR2 | c.11922G>C p.L3974= | Silent (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- SLC6A18 | c.183C>T p.V61= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as COSV57253636; called by muse, mutect2
- SMYD5 | c.1014G>T p.L338= | Silent (SNP) | VAF 25/273 reads (9%) | called by muse, mutect2
- SPTBN2 | c.5826G>A p.A1942= | Silent (SNP) | VAF 161/921 reads (17%) | catalogued as rs373276784; called by muse, mutect2, varscan2
- ST8SIA5 | c.771G>A p.V257= | Silent (SNP) | VAF 103/552 reads (19%) | called by muse, mutect2, varscan2
- TESMIN | c.441A>T p.G147= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, varscan2
- TNRC18 | c.5781G>A p.A1927= | Silent (SNP) | VAF 54/616 reads (9%) | called by muse, mutect2
- UBQLNL | c.1092C>T p.S364= | Silent (SNP) | VAF 34/246 reads (14%) | catalogued as COSV66493618; called by muse, mutect2, varscan2
- VWA8 | c.1254A>C p.S418= | Silent (SNP) | VAF 20/602 reads (3%) | called by muse, mutect2
- ZNF804A | c.2434C>A p.R812= | Silent (SNP) | VAF 37/388 reads (10%) | catalogued as COSV56448307; called by muse, mutect2
- ABCB9 | c.1743+32G>T | Intron (SNP) | VAF 43/222 reads (19%) | catalogued as rs767248694; called by muse, mutect2, varscan2
- AC011487.2 | n.1046G>A | RNA (SNP) | VAF 31/480 reads (6%) | catalogued as rs747641151; called by muse, mutect2
- AK2 | c.*623A>G | 3'UTR (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- AP000769.3 | chr11:65501796 del AAGTT | 5'Flank (DEL) | VAF 33/257 reads (13%) | called by pindel, varscan2
- ATM | c.4436+42T>C | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- COL1A2 | c.2403+11C>A | Intron (SNP) | VAF 31/291 reads (11%) | catalogued as rs754417165; called by muse, mutect2, varscan2
- COL6A1 | c.*705G>T | 3'UTR (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2
- DUSP22 | c.-80C>T | 5'UTR (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- EEF2 | c.*13G>T | 3'UTR (SNP) | VAF 40/298 reads (13%) | called by muse, mutect2, varscan2
- FGB | c.490+40A>C | Intron (SNP) | VAF 21/227 reads (9%) | called by muse, mutect2
- FRYL | c.-81+3586G>T | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- FSIP2 | chr2:185738666 C>A | 5'Flank (SNP) | VAF 44/688 reads (6%) | called by muse, mutect2
- IGHD1-1 | chr14:105922626 T>G | 5'Flank (SNP) | VAF 36/602 reads (6%) | called by muse, mutect2
- IMPA2 | c.381+21C>T | Intron (SNP) | VAF 30/182 reads (16%) | catalogued as COSV52318680; called by muse, mutect2, varscan2
- IQGAP2 | c.1358-1822G>A | Intron (SNP) | VAF 41/368 reads (11%) | called by muse, mutect2, varscan2
- ITK | c.1232+46C>T | Intron (SNP) | VAF 28/338 reads (8%) | catalogued as rs1430152744, COSV70065736; called by muse, mutect2
- KLK2 | c.-22G>T | 5'UTR (SNP) | VAF 22/426 reads (5%) | called by muse, mutect2
- MEIS3 | c.*67G>T | 3'UTR (SNP) | VAF 30/191 reads (16%) | catalogued as rs905947474; called by muse, mutect2, varscan2
- MGAT4FP | n.1055C>A | RNA (SNP) | VAF 42/245 reads (17%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+2528C>G | Intron (SNP) | VAF 98/472 reads (21%) | called by muse, mutect2, varscan2
- NKD2 | c.*86del | 3'UTR (DEL) | VAF 47/300 reads (16%) | called by pindel, varscan2
- OR51F5P | n.164C>A | RNA (SNP) | VAF 32/416 reads (8%) | called by muse, mutect2
- PCDHA10 | c.2388+4693G>A | Intron (SNP) | VAF 22/364 reads (6%) | catalogued as rs782193103; called by muse, mutect2
- PDHA1 | c.760-32T>A | Intron (SNP) | VAF 140/869 reads (16%) | called by muse, mutect2, varscan2
- PRR16 | c.159+16623C>A | Intron (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- RNA5S17 | chr1:228650346 C>T | 5'Flank (SNP) | VAF 40/490 reads (8%) | catalogued as rs749362800; called by muse, mutect2
- TCF4 | c.-492C>G | 5'UTR (SNP) | VAF 64/351 reads (18%) | catalogued as rs753396088; called by muse, mutect2, varscan2
- TTC29 | c.-7+2386T>A | Intron (SNP) | VAF 14/192 reads (7%) | catalogued as rs1163252003; called by muse, mutect2
- TUBB4AP1 | n.545C>A | RNA (SNP) | VAF 86/528 reads (16%) | called by muse, mutect2, varscan2
- TUFT1 | c.*382C>T | 3'UTR (SNP) | VAF 48/249 reads (19%) | called by muse, mutect2, varscan2
